Gene-level copy-number profile of tumor specimen ALCH-AFDS-TTP1-A from ALCHEMIST case ALCH-AFDS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.2 years (27,840 days).
Specimen ALCH-AFDS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1daa52d7-adef-409f-a16b-86ab6fb87f7a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFDS-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/8fed4b3c-4b81-45b5-876b-c2e0ae6f6e76

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 124; copy number 1: 15,279; copy number 2: 43,066; copy number 3: 325; copy number 4: 106; copy number 6: 13.

Homozygous deletions (total copy number 0; autosomes only): 121 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,392,768–160,392,909, 1 gene: RNU4-42P.
- chr8:103,153,394–103,298,772, 1 gene (within-gene range 0–1): BAALC-AS1.
- chr8:103,228,425–103,385,067, 6 genes (within-gene range 0–1): AC025370.1, FZD6, AC025370.2, CTHRC1, AC012213.3, RNU6-1011P.
- chr8:110,334,743–110,349,607, 1 gene: AC073023.1.
- chr8:123,041,968–124,120,061, 33 genes (within-gene range 0–1): TBC1D31, HMGB1P19, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2.
- chr9:19,507,452–23,438,700, 77 genes (broad region; genes not listed).
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:109,240,919–110,105,964, 13 genes, copy number 6: NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, AC023245.1, KCNV1, AC027451.1, RPSAP48.

Autosomal genes at a single copy (total copy number 1): 12,426. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
